Somatic mutation profile of tumor specimen TCGA-78-8660-01A (aliquot TCGA-78-8660-01A-11D-2393-08) from TCGA case TCGA-78-8660, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.6 years (25,422 days).
Specimen TCGA-78-8660-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47068684-1d50-4040-98ac-37e1fc63ca93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-8660-10A (Blood Derived Normal), aliquot TCGA-78-8660-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f1edc95-995a-49aa-88b4-23669a44cf55

The open-access MAF lists 267 somatic variants for this specimen: 198 protein-altering or splice-affecting, 58 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 58, Nonsense Mutation 12, Splice Site 9, Intron 7, Frame Shift Del 6, In Frame Del 2, RNA 2, Frame Shift Ins 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GDF5 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74315388, CM053271, COSV100976762, COSV65502084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 43/396 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2042T>C p.I681T (on ENST00000404938 / NM_001163941.2; = p.I236T on NM_178559.6) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs754874034, COSV99327817; called by muse, mutect2, varscan2
- ABCC9 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99685034; called by muse, mutect2, varscan2
- ACAN | c.1789T>A p.F597I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV100717459; called by muse, mutect2, varscan2
- ACSS3 | c.1010G>T p.W337L | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs762931673, COSV99698487; called by muse, mutect2, varscan2
- ACVR1 | c.737T>C p.F246S | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as CM166932, COSV99717610; called by muse, mutect2
- ADAMTS12 | c.3170C>A p.S1057Y | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100710499; called by muse, mutect2, varscan2
- ADCY2 | c.2066T>G p.I689S | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV100602211; called by muse, varscan2
- ADCY8 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV99651378; called by muse, mutect2, varscan2
- ADD3 | c.178C>G p.Q60E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs781170581, COSV99523263, COSV99523710; called by muse, mutect2, varscan2
- ADGRA3 | c.1648A>C p.T550P | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV99293079; called by muse, mutect2
- AMPD1 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs149424604, COSV100814939; called by muse, mutect2
- ANKRD12 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV50847090; called by muse, mutect2, varscan2
- ARHGAP25 | c.977T>C p.V326A (on ENST00000409202 / NM_001007231.3; = p.V318A on NM_014882.3) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV99771253; called by muse, mutect2, varscan2
- ARMH4 | c.2116G>T p.D706Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99957867; called by muse, varscan2
- ASB15 | c.1601C>A p.P534H | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99306352; called by muse, mutect2, varscan2
- BAZ2B | c.5815A>T p.K1939* | Nonsense Mutation (SNP) | VAF 30/170 reads (18%) | catalogued as COSV100600484; called by muse, mutect2, varscan2
- BMP1 | c.1802C>G p.S601C | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100109260; called by muse, mutect2, varscan2
- BMP7 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV101215720, COSV67782504; called by muse, mutect2, varscan2
- C1orf105 | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100877936, COSV62959572; called by muse, mutect2, varscan2
- CACNA1S | c.4285A>T p.I1429F | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100754803; called by muse, mutect2, varscan2
- CCDC117 | c.326A>T p.E109V | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs770846033, COSV99968819; called by muse, mutect2, varscan2
- CCSER1 | c.578A>T p.K193M | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100389190; called by muse, mutect2, varscan2
- CD1B | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 48/630 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.803); catalogued as COSV100939173; called by muse, mutect2
- CDCP2 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100313388; called by muse, mutect2
- CERS5 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.825); catalogued as COSV100451936; called by muse, mutect2, varscan2
- CES5A | c.51G>C p.W17C | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV99307258; called by muse, mutect2, varscan2
- CHRNA2 | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.044); catalogued as COSV99532045; called by muse, mutect2
- CHUK | c.474+2T>A p.X158_splice | Splice Site (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100957030; called by muse, mutect2
- CLIP1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs761266925, COSV100211420, COSV56799491; called by muse, mutect2, varscan2
- CLRN2 | c.581C>A p.A194D | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV101492686; called by muse, mutect2, varscan2
- CNTNAP5 | c.262A>T p.I88F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV101443194; called by muse, mutect2, varscan2
- CNTNAP5 | c.3787T>A p.Y1263N | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1052752888; called by muse, mutect2
- COL22A1 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100277183; called by muse, mutect2, varscan2
- COL6A3 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as rs763810209, COSV55088249; called by muse, mutect2, varscan2
- CPT1C | c.1194G>C p.K398N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.222); catalogued as rs1445732470, COSV99773250, COSV99773319; called by muse, mutect2, varscan2
- CR2 | c.2810T>C p.V937A | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100889558; called by muse, mutect2, varscan2
- CUBN | c.884-1G>A p.X295_splice | Splice Site (SNP) | VAF 14/129 reads (11%) | catalogued as COSV100912298; called by muse, mutect2, varscan2
- DCDC1 | c.4822del p.V1608Wfs*20 (on ENST00000597505 / NM_001367979.1; = p.V715Wfs*20 on NM_020869.3) | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | catalogued as COSV58003823; called by mutect2, pindel, varscan2
- DCSTAMP | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 36/253 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV99886258; called by muse, mutect2, varscan2
- DISP3 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99607842; called by muse, mutect2
- DMBT1 | c.2045C>G p.P682R | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.889); catalogued as COSV100352503; called by muse, mutect2, varscan2
- DNAAF2 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV53572203; called by muse, mutect2, varscan2
- DNAJC1 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100977996; called by muse, mutect2, varscan2
- DPP6 | c.886G>A p.E296K (on ENST00000377770 / NM_001364500.2; = p.E234K on NM_001936.5) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100124043; called by muse, varscan2
- DPRX | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs373799917, COSV100934065; called by muse, mutect2, varscan2
- EIF3I | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100557161; called by muse, mutect2
- EIF5B | c.2612C>T p.T871I | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99176915; called by muse, mutect2, varscan2
- ELAPOR2 | c.2136C>G p.F712L (on ENST00000450689 / NM_001142749.3; = p.F545L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV99788437; called by muse, mutect2, varscan2
- EML1 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV51742627, COSV99214698; called by muse, mutect2
- EP300 | c.3135G>T p.K1045N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.725); catalogued as COSV54331135, COSV54341065; called by muse, mutect2, varscan2
- EPHA6 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101061369; called by muse, mutect2, varscan2
- ERICH3 | c.3757G>T p.G1253* | Nonsense Mutation (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100443816; called by muse, mutect2
- ERICH6 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99901450; called by muse, mutect2, varscan2
- EXT1 | c.1586G>T p.W529L | Missense Mutation (SNP) | VAF 55/295 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as COSV100983737; called by muse, mutect2, varscan2
- EYS | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV100676032; called by muse, mutect2
- FAM184A | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1186593442, COSV100137563, COSV58856285; called by muse, mutect2, varscan2
- FAM71B | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1340418959, COSV100261949; called by muse, mutect2, varscan2
- FBN2 | c.1213T>A p.C405S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99325920; called by muse, mutect2, varscan2
- FBXL7 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.816); catalogued as rs768251957, COSV61642031; called by muse, mutect2, varscan2
- FMO2 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV99269012; called by muse, mutect2, varscan2
- FOXP4 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100332531; called by muse, mutect2, varscan2
- FRAS1 | c.3536G>T p.R1179L | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV53600910, COSV99349724; called by muse, varscan2
- FRMD8 | c.37C>G p.P13A | Missense Mutation (SNP) | VAF 51/270 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV99587254; called by muse, mutect2, varscan2
- GABRB1 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54969925; called by muse, mutect2, varscan2
- GAL3ST3 | c.660C>A p.D220E | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as COSV100360771; called by muse, mutect2
- GAPVD1 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as rs1158458070, COSV99782878; called by muse, mutect2, varscan2
- GBA3 | c.780C>G p.I260M | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.105); catalogued as COSV101545486; called by muse, mutect2, varscan2
- GPC5 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.086); catalogued as COSV100993212; called by muse, mutect2, varscan2
- GPR26 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as COSV99500772, COSV99500809; called by muse, mutect2, varscan2
- GPR35 | c.619G>T p.G207W | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.806); catalogued as COSV100166384; called by muse, mutect2, varscan2
- GRAMD4 | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100730385, COSV100730600; called by mutect2, varscan2
- HEPH | c.3151C>A p.H1051N (on ENST00000343002; = p.H784N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294402; called by muse, mutect2, varscan2
- HPSE2 | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100985430; called by muse, mutect2
- IER5 | c.293C>T p.T98I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.061); catalogued as COSV100849675; called by muse, mutect2, varscan2
- IFI35 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs1405141914, COSV99518457; called by muse, mutect2, varscan2
- IGKV1D-8 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs566034595; called by muse, mutect2, varscan2
- INTU | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99611504; called by muse, mutect2, varscan2
- ITGAX | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191548; called by muse, mutect2, varscan2
- ITPR2 | c.1414G>C p.V472L | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); catalogued as COSV101189888; called by muse, mutect2
- KANK1 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV63217112; called by muse, mutect2, varscan2
- KANSL1 | c.2423C>A p.S808* | Nonsense Mutation (SNP) | VAF 31/135 reads (23%) | catalogued as COSV99294255; called by muse, mutect2, varscan2
- KCNB2 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101578707, COSV73048983; called by muse, mutect2, varscan2
- KIF2B | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV52129299, COSV99274948; called by muse, varscan2
- KLHL1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as COSV100917112; called by muse, mutect2, varscan2
- KLHL24 | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99664798; called by muse, mutect2
- KMT2A | c.3635-2A>T p.X1212_splice | Splice Site (SNP) | VAF 42/154 reads (27%) | catalogued as COSV100628330; called by muse, mutect2, varscan2
- KRBA1 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV55444936, COSV99752353; called by muse, mutect2, varscan2
- LARP7 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100135031; called by muse, mutect2, varscan2
- LILRB4 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV99553625; called by muse, mutect2
- LIMK1 | c.1391A>T p.H464L | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV100283041, COSV100283073; called by muse, mutect2, varscan2
- MC3R | c.253A>T p.M85L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV99710496; called by muse, mutect2, varscan2
- MDGA2 | c.1855C>T p.R619W (on ENST00000399232 / NM_001113498.2; = p.R321W on NM_182830.4) | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs766117441, COSV62094062; called by muse, mutect2, varscan2
- MICU3 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536192; called by muse, mutect2, varscan2
- MMUT | c.1202G>C p.S401T | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV99222229; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100825012; called by muse, mutect2, varscan2
- MPPED2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV63901487; called by muse, mutect2, varscan2
- MRPS7 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs778531303, COSV99821525; called by muse, mutect2
- MUC6 | c.3379T>A p.C1127S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101424466; called by muse, mutect2
- MYO3A | c.586-1G>A p.X196_splice | Splice Site (SNP) | VAF 15/212 reads (7%) | catalogued as rs1456340767, COSV99778890; called by muse, mutect2
- NES | c.2907G>C p.M969I | Missense Mutation (SNP) | VAF 82/528 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100957804; called by muse, mutect2, varscan2
- NEUROD1 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99716847; called by mutect2, varscan2
- NEXMIF | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV50042311, COSV99280176; called by muse, mutect2, varscan2
- NIPBL | c.6238T>C p.Y2080H | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99239622; called by muse, mutect2, varscan2
- NRK | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.333); catalogued as COSV99687046; called by muse, mutect2, varscan2
- NSD1 | c.4379-1G>T p.X1460_splice | Splice Site (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100728613; called by muse, mutect2
- NSD1 | c.4379G>T p.G1460V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100728614; called by muse, mutect2
- NTSR2 | c.854A>C p.D285A | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV100183845; called by muse, mutect2, varscan2
- OGDHL | c.693G>T p.M231I | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV100934229, COSV65102293; called by muse, mutect2, varscan2
- OR10X1 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV100936617; called by muse, mutect2, varscan2
- OR10Z1 | c.321G>T p.W107C | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100778969; called by muse, mutect2, varscan2
- OR2G6 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as COSV99080274; called by muse, mutect2, varscan2
- OR4C15 | c.409G>T p.D137Y (on ENST00000314644; = p.D83Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58952084; called by muse, mutect2, varscan2
- OR51V1 | c.585C>G p.I195M | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100343297; called by muse, mutect2
- OR5F1 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53549353, COSV99558485; called by muse, mutect2, varscan2
- OR8K3 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100449712; called by muse, mutect2, varscan2
- OR8K3 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV100449715, COSV100449788; called by muse, mutect2, varscan2
- OR9A4 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV101516373; called by muse, mutect2, varscan2
- OVCH1 | c.2330T>A p.V777D | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100548345; called by muse, mutect2, varscan2
- PASD1 | c.1350G>T p.K450N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100949194, COSV64857142; called by muse, mutect2
- PCDH11X | c.4001C>G p.P1334R | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100009965, COSV53445042, COSV53490727; called by muse, mutect2, varscan2
- PCDHB6 | c.1469C>A p.P490Q | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99169997; called by muse, mutect2, varscan2
- PCDHGA3 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.087); catalogued as rs777942977, COSV99533838, COSV99548014; called by muse, mutect2, varscan2
- PDYN | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54102914, COSV99452835; called by muse, mutect2, varscan2
- PGBD1 | c.553+1G>C p.X185_splice | Splice Site (SNP) | VAF 12/121 reads (10%) | catalogued as COSV99459901; called by muse, mutect2
- PNPT1 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 24/129 reads (19%) | catalogued as COSV53178103, COSV99569778; called by muse, mutect2, varscan2
- POF1B | c.1428C>A p.C476* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99426288; called by muse, mutect2, varscan2
- POGLUT3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV100052577; called by muse, mutect2, varscan2
- POSTN | c.895G>C p.A299P | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV101123280, COSV101123367, COSV65713066; called by muse, mutect2, varscan2
- POTEF | c.2281A>C p.K761Q | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100664714; called by muse, mutect2, varscan2
- PRKDC | c.6551A>G p.Y2184C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1482038164, COSV100039211; called by muse, mutect2, varscan2
- PROC | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 29/293 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV99300707; called by muse, mutect2, varscan2
- PTCHD3 | c.1874A>C p.E625A | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101438878; called by muse, mutect2
- PTK2B | c.670-1G>T p.X224_splice | Splice Site (SNP) | VAF 19/124 reads (15%) | catalogued as COSV100593598; called by muse, mutect2, varscan2
- PTPRD | c.5540G>T p.G1847V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100643962, COSV100647403; called by muse, mutect2, varscan2
- RTN3 | c.271G>A p.E91K (on ENST00000377819 / NM_001265589.2; = p.E72K on NM_201428.3) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1252131448, COSV100127398; called by muse, mutect2, varscan2
- RUBCNL | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100528914; called by muse, mutect2, varscan2
- RYR2 | c.1389C>A p.F463L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100768939; called by muse, mutect2, varscan2
- RYR2 | c.5688G>A p.M1896I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.218); catalogued as COSV100768940, COSV100772267; called by muse, mutect2, varscan2
- RYR2 | c.6169A>T p.T2057S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.178); catalogued as COSV100768941; called by muse, mutect2
- RYR2 | c.8211G>C p.L2737F | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as COSV100768942; called by muse, mutect2
- SACS | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV101207261; called by muse, mutect2
- SENP2 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs199858955; called by muse, mutect2, varscan2
- SERPINA9 | c.1118A>T p.K373M | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100098073; called by muse, mutect2, varscan2
- SERPINE3 | c.808dup p.L270Pfs*33 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | catalogued as rs753981280; called by mutect2, pindel, varscan2
- SLAMF8 | c.365A>T p.Y122F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56988268, COSV99222766; called by muse, mutect2, varscan2
- SLAMF8 | c.366C>A p.Y122* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as rs199758683, COSV99222772; called by muse, mutect2, varscan2
- SLC17A7 | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99676745; called by muse, mutect2, varscan2
- SLCO2A1 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.548); catalogued as COSV100188761; called by muse, mutect2, varscan2
- SLITRK3 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV53847250; called by muse, mutect2, varscan2
- SMARCA4 | c.1523A>C p.H508P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100758273; called by muse, mutect2, varscan2
- SMARCA5 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99303615; called by muse, mutect2, varscan2
- SMPD4 | c.2038A>T p.T680S (on ENST00000409031 / NM_017951.4; = p.T651S on NM_017751.4) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.275); catalogued as COSV100302276; called by muse, mutect2, varscan2
- SNAI2 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194940; called by muse, mutect2, varscan2
- SNX11 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100821723, COSV63658321; called by mutect2, varscan2
- SPHKAP | c.3500C>G p.A1167G | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV100763867; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 6/136 reads (4%) | PolyPhen probably damaging (0.995); catalogued as COSV100082265; called by muse, mutect2
- TAMM41 | c.653G>A p.S218N | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1461273717, COSV99808740; called by muse, mutect2, varscan2
- TBL3 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs766553339, COSV100224761; called by muse, mutect2, varscan2
- TOX | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 38/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812630; called by muse, mutect2, varscan2
- TP53 | c.441del p.D148Ifs*22 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | catalogued as COSV53407453; called by mutect2, pindel, varscan2
- TTN | c.68022C>A p.Y22674* (on ENST00000591111; = p.Y15250* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | catalogued as CM161145, COSV100601235; called by muse, varscan2
- TUBG1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV99258496; called by muse, mutect2, varscan2
- UGT2B4 | c.1090+2T>A p.X364_splice | Splice Site (SNP) | VAF 33/215 reads (15%) | catalogued as COSV100522296; called by muse, mutect2, varscan2
- UNC45B | c.821A>G p.D274G | Missense Mutation (SNP) | VAF 48/750 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV99268388; called by muse, mutect2
- USP8 | c.1913G>C p.R638T | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1279895759, COSV100208863, COSV56165116; called by muse, mutect2, varscan2
- WDR81 | c.3957C>G p.I1319M (on ENST00000409644 / NM_001163809.2; = p.I268M on NM_152348.4) | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.974); catalogued as COSV100488696; called by muse, mutect2, varscan2
- XYLT1 | c.2468T>A p.V823E | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99760877; called by muse, mutect2, varscan2
- ZBED1 | c.1827G>T p.W609C | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100585359; called by muse, mutect2, varscan2
- ZEB2 | c.3015C>A p.D1005E | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV57962810; called by muse, mutect2, varscan2
- ZNF208 | c.2491A>C p.K831Q | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101236920; called by muse, mutect2, varscan2
- ZNF257 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1380622609, COSV101448066; called by muse, mutect2, varscan2
- ZNF264 | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99567170; called by muse, mutect2, varscan2
- ZNF43 | c.2353A>T p.T785S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV100731739; called by muse, mutect2, varscan2
- ZNF44 | c.787C>T p.H263Y (on ENST00000356109 / NM_001164276.2; = p.H215Y on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633514; called by muse, mutect2
- ZNF486 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100631141; called by muse, mutect2, varscan2
- ZNF486 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781968701, COSV100631143; called by muse, mutect2, varscan2
- ZNF521 | c.2176C>A p.L726I | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831675; called by muse, mutect2, varscan2
- ZNF524 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV99684502; called by muse, mutect2
- ZNF707 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1443490506, COSV100690545; called by muse, mutect2, varscan2
- ZNF768 | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.319); catalogued as COSV99411413; called by muse, mutect2, varscan2
- ZNF804B | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1287035066, COSV100302628; called by muse, mutect2, varscan2
- ZNF878 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | catalogued as COSV101521186; called by muse, mutect2
- BRAF | c.1918_1929del p.V640_R643del (on ENST00000288602 / NM_001374244.1; = p.V600_R603del on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 17/142 reads (12%) | called by mutect2, pindel
- FCGR1A | c.691A>T p.M231L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2
- FIP1L1 | c.1415_1424del p.D472Gfs*147 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | called by pindel, varscan2
- H1-2 | c.192dup p.A65Sfs*8 | Frame Shift Ins (INS) | VAF 50/234 reads (21%) | called by mutect2, pindel, varscan2
- LRP1 | c.10711A>G p.T3571A | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- NKX2-2 | c.266del p.G89Vfs*95 | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | called by mutect2, pindel, varscan2
- PCDHB9 | c.2092T>A p.S698T | Missense Mutation (SNP) | VAF 46/335 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PDZRN3 | c.2798T>G p.I933S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PIP4K2B | c.507+1G>C p.X169_splice | Splice Site (SNP) | VAF 28/137 reads (20%) | called by muse, mutect2, varscan2
- PLCD4 | c.820_843del p.C274_F281del | In Frame Del (DEL) | VAF 20/181 reads (11%) | called by mutect2, pindel
- SOX11 | c.147del p.K50Sfs*4 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- TAF6L | c.1778del p.R593Pfs*8 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel*, varscan2
- TPTE | c.424C>A p.L142I (on ENST00000618007 / NM_199261.4; = p.L124I on NM_199259.4) | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, mutect2
- ADCY2 | c.900C>A p.T300= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV100602210, COSV57865933, COSV57867708; called by muse, mutect2, varscan2
- ANGPT2 | c.523T>C p.L175= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100290771; called by muse, mutect2, varscan2
- ATP2B2 | c.1710G>A p.K570= (on ENST00000352432; = p.K536= on NM_001683.5) | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as COSV100659867; called by muse, mutect2, varscan2
- BLZF1 | c.150A>T p.P50= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV100250548; called by muse, mutect2, varscan2
- BMP7 | c.942G>T p.R314= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV101215719; called by muse, mutect2, varscan2
- BRWD1 | c.5694C>T p.S1898= | Silent (SNP) | VAF 30/184 reads (16%) | catalogued as COSV100313075; called by muse, mutect2, varscan2
- CDH18 | c.753T>C p.S251= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV99933092; called by muse, mutect2, varscan2
- CFAP58 | c.2604C>A p.T868= | Silent (SNP) | VAF 34/180 reads (19%) | catalogued as COSV100866063; called by muse, mutect2, varscan2
- CTNNA2 | c.939C>G p.G313= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as COSV100782546; called by muse, mutect2, varscan2
- CYP7A1 | c.534G>C p.V178= | Silent (SNP) | VAF 18/249 reads (7%) | catalogued as COSV100052235; called by muse, mutect2
- DDX49 | c.186G>A p.Q62= | Silent (SNP) | VAF 14/153 reads (9%) | catalogued as COSV99447308; called by muse, mutect2
- EFTUD2 | c.204A>T p.T68= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV101274525; called by muse, mutect2, varscan2
- FAM120B | c.1887C>G p.V629= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV99379114; called by muse, mutect2, varscan2
- FARSB | c.1188C>T p.L396= | Silent (SNP) | VAF 25/198 reads (13%) | catalogued as COSV99918243; called by muse, mutect2, varscan2
- FCRL3 | c.729C>A p.P243= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as COSV100942997; called by muse, mutect2, varscan2
- FCRL5 | c.2205C>T p.A735= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV100708691; called by muse, mutect2, varscan2
- FGD4 | c.375G>T p.T125= | Silent (SNP) | VAF 36/203 reads (18%) | catalogued as COSV99846881; called by muse, mutect2, varscan2
- FOXL1 | c.330G>T p.V110= | Silent (SNP) | VAF 43/253 reads (17%) | catalogued as rs1027894858, COSV100206154; called by muse, mutect2, varscan2
- GALNS | c.951G>T p.G317= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV51936373, COSV51941657; called by muse, mutect2, varscan2
- GALNT10 | c.255G>A p.Q85= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV99768496; called by muse, mutect2
- GDF6 | c.1242C>A p.S414= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99747816; called by muse, mutect2, varscan2
- HAPLN3 | c.984G>A p.P328= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs528539488, COSV61364912; called by muse, mutect2, varscan2
- HOXD13 | c.444G>A p.Q148= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV101184188; called by muse, mutect2, varscan2
- HS3ST3A1 | c.789C>A p.I263= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV99404142; called by mutect2, varscan2
- IDH3B | c.54G>T p.G18= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV101077098; called by muse, mutect2, varscan2
- ITPRIP | c.1191G>A p.K397= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV99532458; called by muse, mutect2, varscan2
- KLHL6 | c.1293C>A p.G431= | Silent (SNP) | VAF 38/273 reads (14%) | catalogued as COSV100384437; called by muse, mutect2
- KLK5 | c.828G>T p.T276= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as COSV100306928; called by muse, mutect2, varscan2
- LIMK1 | c.1683C>G p.L561= | Silent (SNP) | VAF 44/331 reads (13%) | catalogued as COSV100283075; called by muse, mutect2, varscan2
- LINS1 | c.2133A>G p.R711= | Silent (SNP) | VAF 51/333 reads (15%) | catalogued as COSV100130064, COSV59080249; called by muse, mutect2, varscan2
- LRFN1 | c.1632C>T p.I544= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99952764; called by muse, mutect2, varscan2
- MAP3K6 | c.1863G>T p.T621= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100709111, COSV100709382; called by muse, mutect2, varscan2
- MRS2 | c.939T>C p.L313= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV99218801; called by muse, mutect2, varscan2
- NUP214 | c.3300G>A p.Q1100= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs749116136, COSV100845194; called by muse, mutect2, varscan2
- OPRK1 | c.1041A>G p.P347= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs763088113, COSV55571266; called by muse, mutect2, varscan2
- OR10A6 | c.279T>C p.S93= | Silent (SNP) | VAF 29/305 reads (10%) | catalogued as COSV100564254; called by muse, mutect2
- OR2T3 | c.921G>A p.R307= | Silent (SNP) | VAF 27/554 reads (5%) | catalogued as rs1328794541, COSV62081740, COSV62082153; called by muse, mutect2
- OR51B5 | c.411T>C p.T137= | Silent (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100332484; called by muse, mutect2, varscan2
- OR5L2 | c.675C>A p.I225= | Silent (SNP) | VAF 22/224 reads (10%) | catalogued as COSV101004267, COSV65723787, COSV65725524; called by muse, mutect2
- OR8I2 | c.258A>G p.Q86= | Silent (SNP) | VAF 42/337 reads (12%) | catalogued as rs766593939, COSV100135941; called by muse, mutect2, varscan2
- PER1 | c.462G>T p.R154= | Silent (SNP) | VAF 92/300 reads (31%) | catalogued as COSV100424379; called by muse, mutect2, varscan2
- PHLDB3 | c.207C>T p.R69= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99415306; called by muse, mutect2, varscan2
- PLD5 | c.651C>G p.G217= (on ENST00000442594; = p.G155= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV100139507; called by muse, mutect2, varscan2
- RUSC1 | c.636C>G p.L212= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as COSV99429609; called by muse, mutect2, varscan2
- SHOC1 | c.381C>A p.I127= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs767454352, COSV100597411; called by muse, mutect2, varscan2
- STARD7 | c.862C>T p.L288= | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV100474564; called by muse, mutect2, varscan2
- TENT4A | c.1623G>A p.V541= | Silent (SNP) | VAF 52/389 reads (13%) | catalogued as COSV100048749, COSV50098158; called by muse, mutect2, varscan2
- THBS4 | c.414C>G p.A138= | Silent (SNP) | VAF 19/185 reads (10%) | catalogued as rs756889254, COSV100644224; called by muse, mutect2, varscan2
- TMPRSS11B | c.537C>A p.I179= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV100219280; called by muse, mutect2, varscan2
- TRPV6 | c.600C>T p.I200= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs760075855, COSV100844195; called by muse, mutect2, varscan2
- TTN | c.68103C>A p.I22701= (on ENST00000591111; = p.I15277= on NM_003319.4) | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100601232, COSV60213455; called by muse, varscan2
- USP8 | c.3297A>T p.S1099= | Silent (SNP) | VAF 18/138 reads (13%) | catalogued as COSV100208864; called by muse, mutect2, varscan2
- VIPR1 | c.546C>T p.F182= | Silent (SNP) | VAF 15/243 reads (6%) | catalogued as COSV100285553; called by muse, mutect2
- WSCD2 | c.1656G>C p.G552= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV99774288; called by muse, mutect2, varscan2
- XIRP2 | c.2421C>T p.L807= (on ENST00000628543; = p.L982= on NM_152381.6) | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as rs760576873, COSV99740432; called by muse, mutect2, varscan2
- ZBTB47 | c.1335C>T p.F445= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99234013; called by muse, mutect2
- ZC3H13 | c.2340G>A p.R780= | Silent (SNP) | VAF 24/280 reads (9%) | catalogued as COSV99667738; called by muse, mutect2
- ZFPM2 | c.3156G>A p.E1052= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV101023096; called by muse, mutect2
- AC073310.1 | n.883T>C | RNA (SNP) | VAF 38/199 reads (19%) | called by muse, mutect2, varscan2
- AGPAT4 | c.843+2313G>A | Intron (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- DCHS2 | n.2017dup | RNA (INS) | VAF 24/252 reads (10%) | called by mutect2, pindel
- DEPDC5 | c.*1014G>T | 3'UTR (SNP) | VAF 64/368 reads (17%) | catalogued as COSV99834782; called by muse, mutect2, varscan2
- GABRA3 | c.-26-28891G>A | Intron (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100942441, COSV100942499; called by muse, mutect2, varscan2
- MFSD11 | chr17:76737095 G>C | 5'Flank (SNP) | VAF 5/28 reads (18%) | catalogued as COSV100333627; called by muse, mutect2
- MIF4GD | c.82+731C>T | Intron (SNP) | VAF 26/243 reads (11%) | catalogued as rs754593361, COSV99821526; called by muse, mutect2, varscan2
- PCDH15 | c.92-523T>C | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as rs1323421882; called by muse, mutect2
- RUSC1 | c.-87+151C>T | Intron (SNP) | VAF 8/49 reads (16%) | catalogued as rs750012837, COSV99429603; called by muse, mutect2, varscan2
- RUSC1 | c.-87+315C>G | Intron (SNP) | VAF 3/27 reads (11%) | catalogued as COSV99429605; called by muse, mutect2
- RUSC1 | c.-86-263C>G | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as COSV99429607; called by muse, mutect2, varscan2
